Somatic mutation profile of tumor specimen ER-AC0F-TTP2-A (aliquot ER-AC0F-TTP2-A-1-0-D-A598-34) from EXCEPTIONAL_RESPONDERS case ER-AC0F, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.2 years (21,260 days).
Specimen ER-AC0F-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06b73c3a-4660-45cc-91b4-e27d06ff655c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AC0F-NT1-A (Solid Tissue Normal), aliquot ER-AC0F-NT1-A-2-0-D-A598-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c1959da-663d-4057-9341-c6828f1b6915

The open-access MAF lists 86 somatic variants for this specimen: 64 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 18, Frame Shift Del 3, Intron 2, Nonsense Mutation 2, 3'Flank 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 53/135 reads (39%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACAN | c.5986G>A p.G1996R | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs377010256; called by muse, mutect2, varscan2
- BTNL3 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV61564678; called by muse, mutect2
- CDK5RAP1 | c.1376C>G p.S459C (on ENST00000357886 / NM_001365728.1; = p.S445C on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs929465491; called by muse, mutect2, varscan2
- COMMD10 | c.487G>C p.G163R | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57236754, COSV99174503; called by muse, mutect2, varscan2
- EPHB1 | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 86/253 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as rs534330476, COSV67653771, COSV67669910; called by muse, mutect2, varscan2
- FBXO31 | c.404A>C p.Y135S | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100291629; called by muse, mutect2, varscan2
- FIGN | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV60769652; called by muse, mutect2, varscan2
- FOLR3 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as rs752978331, COSV61530160; called by muse, mutect2, varscan2
- GABRA5 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59481799; called by muse, mutect2, varscan2
- GSN | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV57998823, COSV58001210; called by muse, mutect2, varscan2
- KIF2B | c.181G>T p.V61L | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV52135739; called by muse, mutect2, varscan2
- MLLT6 | c.3123_3128del p.A1046_A1047del | In Frame Del (DEL) | VAF 17/110 reads (15%) | catalogued as rs767745562; called by mutect2, pindel, varscan2
- MTUS2 | c.115C>G p.Q39E | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs754856642, COSV70913373; called by muse, mutect2, varscan2
- MXRA5 | c.8365C>A p.L2789I | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99475584; called by muse, mutect2, varscan2
- NFATC1 | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs1246478854; called by muse, mutect2, varscan2
- OR7C2 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1259197202; called by muse, mutect2, varscan2
- P2RY1 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59310030; called by muse, mutect2, varscan2
- PDE1B | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775517543; called by muse, mutect2, varscan2
- PDHX | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 37/152 reads (24%) | catalogued as rs766377898, CM102811, COSV57164936; called by muse, mutect2, varscan2
- SAMSN1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs1244421634; called by muse, mutect2, varscan2
- SEMA3G | c.1699G>C p.G567R | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51593801; called by muse, mutect2
- SLC22A5 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as rs1156522490; called by muse, mutect2, varscan2
- STAG3 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs539912996, COSV57933950; called by muse, mutect2, varscan2
- XIRP1 | c.2054G>C p.R685P | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs759311655, COSV61138425; called by muse, mutect2, varscan2
- ZDHHC8 | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV57712692; called by muse, mutect2, varscan2
- ZNF296 | c.1309G>T p.G437C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55519891; called by muse, mutect2, varscan2
- ZNF546 | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs201146765; called by muse, mutect2, varscan2
- ACAT1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 163/316 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM22 | c.254A>T p.H85L | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALS2 | c.3271A>G p.N1091D | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARHGAP26 | c.1287C>A p.D429E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2
- BLM | c.1172T>C p.L391P | Missense Mutation (SNP) | VAF 27/363 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CCDC149 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC61 | c.1355G>T p.S452I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CDH6 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- CFAP70 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- CIPC | c.249G>C p.K83N | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A6 | c.4916C>G p.A1639G | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DENND4C | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DHX40 | c.134A>G p.Q45R | Missense Mutation (SNP) | VAF 282/382 reads (74%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- DNAAF5 | c.1995T>G p.H665Q | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- GLCE | c.746A>T p.D249V | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- HACE1 | c.1674C>G p.H558Q | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- HFE | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP2 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- IGLV3-27 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL34 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); called by muse, mutect2
- LAMA5 | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.214); called by muse, mutect2
- MAP7D1 | c.1584G>C p.Q528H | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MKI67 | c.2778A>T p.E926D | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- MYH7B | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PEAK1 | c.3515T>A p.L1172H | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PLXDC1 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 240/1292 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2
- POLQ | c.3751C>T p.H1251Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PRAG1 | c.2795G>A p.G932E | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.287); called by muse, mutect2
- PRC1 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PSPC1 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SETBP1 | c.1588C>T p.R530* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- SETD4 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC20A1 | c.1071_1072del p.N358Pfs*25 | Frame Shift Del (DEL) | VAF 15/100 reads (15%) | called by mutect2, pindel, varscan2
- SLC2A11 | c.163G>A p.G55R (on ENST00000345044 / NM_001024938.4; = p.G62R on NM_030807.5) | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- USP9X | c.7054del p.T2352Lfs*8 | Frame Shift Del (DEL) | VAF 64/231 reads (28%) | called by mutect2, pindel, varscan2
- VIRMA | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ACAA1 | c.45C>G p.A15= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- CDR1 | c.612G>A p.K204= | Silent (SNP) | VAF 369/792 reads (47%) | catalogued as COSV100983406; called by muse, mutect2, varscan2
- CLEC14A | c.681C>T p.I227= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV60563388; called by muse, mutect2, varscan2
- CRYBG3 | c.6615C>T p.T2205= | Silent (SNP) | VAF 39/233 reads (17%) | called by muse, mutect2, varscan2
- CUX1 | c.3207C>T p.S1069= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs782113783; called by muse, mutect2, varscan2
- ERBB2 | c.321C>G p.L107= | Silent (SNP) | VAF 92/1904 reads (5%) | catalogued as COSV54070774; called by muse, mutect2
- GSE1 | c.2610C>T p.F870= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as rs1182629889; called by muse, mutect2, varscan2
- HS6ST2 | c.996G>A p.L332= | Silent (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- MBLAC1 | c.618G>C p.L206= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99498886; called by muse, varscan2
- NBEAL2 | c.6411G>C p.V2137= | Silent (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- OR4C13 | c.585C>T p.L195= | Silent (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- RPS19BP1 | c.216C>G p.L72= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV58180378; called by muse, mutect2, varscan2
- RYR1 | c.7047C>T p.N2349= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as rs149295336; called by muse, mutect2, varscan2
- SPAG4 | c.351C>A p.L117= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- SQLE | c.489T>G p.V163= | Silent (SNP) | VAF 83/1430 reads (6%) | called by muse, mutect2
- TRIM63 | c.627G>C p.L209= | Silent (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- ZFR | c.2355G>A p.L785= | Silent (SNP) | VAF 101/370 reads (27%) | catalogued as COSV54059160; called by muse, mutect2, varscan2
- ZNF829 | c.1116A>G p.R372= | Silent (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149864 C>T | 5'Flank (SNP) | VAF 10/44 reads (23%) | catalogued as rs371817165; called by muse, varscan2
- CHRM2 | chr7:137016489 G>T | 3'Flank (SNP) | VAF 44/249 reads (18%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+13526_1514+13529del | Intron (DEL) | VAF 206/484 reads (43%) | catalogued as rs1315786246; called by mutect2, varscan2
- STARD8 | c.-7-1070T>A | Intron (SNP) | VAF 31/202 reads (15%) | called by muse, mutect2, varscan2
